Somatic mutation profile of tumor specimen TCGA-AB-2851-03B (aliquot TCGA-AB-2851-03B-01W-0728-08) from TCGA case TCGA-AB-2851, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute monocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.6 years (24,319 days).
Specimen TCGA-AB-2851-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77bacd48-34ce-4a40-aed7-b507caf8acd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2851-11B (Solid Tissue Normal), aliquot TCGA-AB-2851-11B-01W-0729-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac8a555e-8442-493c-b777-6eabc065699a

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SFT2D1 | c.316-2A>T p.X106_splice | Splice Site (SNP) | VAF 7/70 reads (10%) | catalogued as COSV100674938, COSV100674968; called by muse, mutect2
